Somatic mutation profile of tumor specimen TCGA-DU-A7TA-01A (aliquot TCGA-DU-A7TA-01A-11D-A33T-08) from TCGA case TCGA-DU-A7TA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.2 years (11,764 days).
Specimen TCGA-DU-A7TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe5d8aed-8168-43a6-8557-dc985e471832.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7TA-10A (Blood Derived Normal), aliquot TCGA-DU-A7TA-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/225c238c-01da-49c0-90dc-0ef20d72a902

The open-access MAF lists 39 somatic variants for this specimen: 36 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 22, Frame Shift Del 6, Nonsense Mutation 4, In Frame Del 3, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 51/126 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 50/152 reads (33%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, varscan2
- ARHGAP20 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 14/455 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99504148; called by muse, mutect2
- ATP13A5 | c.2027T>G p.L676* | Nonsense Mutation (SNP) | VAF 123/285 reads (43%) | catalogued as COSV100665183; called by muse, mutect2, varscan2
- ATP2B2 | c.3350T>G p.I1117S (on ENST00000352432; = p.I1083S on NM_001683.5) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100659983; called by muse, mutect2
- ATRX | c.6875del p.P2292Qfs*28 | Frame Shift Del (DEL) | VAF 142/220 reads (65%) | catalogued as COSV100970927; called by mutect2, pindel, varscan2
- CHCHD4 | c.302A>C p.Y101S (on ENST00000396914 / NM_001098502.2; = p.Y114S on NM_144636.3) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV99853957; called by muse, mutect2, varscan2
- ERCC8 | c.1205C>T p.P402L (on ENST00000265038; = p.P383L on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as rs754566666, COSV54017986; called by muse, mutect2, varscan2
- ERICH3 | c.1484A>G p.K495R | Missense Mutation (SNP) | VAF 102/237 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100444457; called by muse, mutect2, varscan2
- ERMN | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.847); catalogued as COSV101263044, COSV68075144; called by muse, mutect2, varscan2
- FAM111B | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs374133736; called by muse, mutect2, varscan2
- GLI3 | c.1010T>A p.L337* | Nonsense Mutation (SNP) | VAF 59/197 reads (30%) | catalogued as COSV101229885; called by muse, mutect2, varscan2
- ITGA4 | c.1205T>C p.I402T | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52001291, COSV99276365; called by muse, mutect2, varscan2
- KCNJ9 | c.199G>C p.A67P | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV100927751, COSV63632387; called by muse, mutect2
- LCOR | c.1655G>C p.R552T | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs1184202098, COSV99616919; called by muse, mutect2, varscan2
- LRP1B | c.7702G>T p.G2568C | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as COSV101257504; called by muse, mutect2, varscan2
- LRRC37A | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 85/132 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778412898, COSV100208187; called by muse, mutect2, varscan2
- MUC16 | c.32251A>G p.T10751A | Missense Mutation (SNP) | VAF 157/350 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs1448752869, COSV101200018; called by muse, mutect2
- NEBL | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.739); catalogued as COSV101009219, COSV99058389; called by muse, mutect2, varscan2
- PPM1K | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1427854407, COSV99900996; called by muse, mutect2, varscan2
- RBBP5 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV99196817; called by muse, mutect2, varscan2
- RP1 | c.753C>G p.Y251* | Nonsense Mutation (SNP) | VAF 58/183 reads (32%) | catalogued as COSV99607592; called by muse, mutect2, varscan2
- SMURF1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs1238372679, COSV100742469; called by muse, mutect2
- UGGT2 | c.531_534del p.N177Kfs*7 | Frame Shift Del (DEL) | VAF 42/106 reads (40%) | catalogued as rs751349526; called by pindel, varscan2
- USP6 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as rs1231449094, COSV100004060; called by muse, mutect2, varscan2
- VPS50 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99298185; called by muse, mutect2, varscan2
- WDR19 | c.3471T>A p.Y1157* | Nonsense Mutation (SNP) | VAF 27/136 reads (20%) | catalogued as COSV99975518; called by muse, mutect2, varscan2
- ZNF8 | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99544162, COSV99544522; called by muse, mutect2, varscan2
- ZSCAN5A | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV99570210; called by muse, mutect2, varscan2
- DYNC2I1 | c.548_551del p.R183Kfs*134 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- KIF24 | c.112_114del p.K38del | In Frame Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- PSIP1 | c.1021_1023del p.E341del | In Frame Del (DEL) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- RGS4 | c.464_466del p.K155del | In Frame Del (DEL) | VAF 243/685 reads (35%) | called by pindel, varscan2
- SEC14L2 | c.694_695del p.I232Qfs*3 | Frame Shift Del (DEL) | VAF 40/110 reads (36%) | called by pindel, varscan2
- SMG1 | c.10778_10781del p.V3593Efs*17 | Frame Shift Del (DEL) | VAF 62/187 reads (33%) | called by mutect2, pindel, varscan2
- TP53 | c.363dup p.V122Cfs*27 | Frame Shift Ins (INS) | VAF 60/175 reads (34%) | called by mutect2, pindel, varscan2
- GPRIN1 | c.558G>A p.E186= | Silent (SNP) | VAF 66/181 reads (36%) | catalogued as COSV99991650; called by muse, mutect2, varscan2
- KEAP1 | c.1218C>T p.C406= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs762516594, COSV99407805; called by muse, mutect2, varscan2
- PTGS2 | c.897C>T p.C299= | Silent (SNP) | VAF 64/296 reads (22%) | catalogued as rs201011990, COSV66568388; called by muse, varscan2
